Gene-level copy-number profile of tumor specimen C3L-07676-02 from CPTAC case C3L-07676, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 67.4 years (24,609 days).
Specimen C3L-07676-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 095654eb-5338-441f-bcae-b150b7a7e838.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07676-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/96ab480b-2d60-4089-868f-410c95dd9dfe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 797; copy number 2: 30,059; copy number 3: 20,642; copy number 4: 2,495; copy number 5: 2,674; copy number 6: 762; copy number 7: 668; copy number 8: 189; copy number 9: 2; copy number 10: 53; copy number 11: 11; copy number 12: 8; copy number 13: 26; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–2): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr17:17,972,813–18,039,209, 5 genes (within-gene range 0–2): DRC3, ATPAF2, BRI3P3, AC087163.1, AC087163.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,396 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,540,768–168,582,069, 4 genes, copy number 6: XCL2, AL031736.1, XCL1, AL031736.2.
- chr2:43,091,388–43,132,482, 2 genes, copy number 6: RNU6-242P, LINC02580.
- chr2:81,666,477–82,005,700, 3 genes, copy number 5: AC013262.1, RN7SL201P, AC079896.1.
- chr5:58,198–45,895,970, 679 genes, copy number 7–15 (broad region; genes not listed).
- chr6:20,099,684–20,317,739, 3 genes, copy number 6: MBOAT1, AL158198.1, AL158198.2.
- chr7:159,028,175–159,233,377, 3 genes, copy number 8 (within-gene range 3–8): VIPR2, AC007269.1, PIP5K1P2.
- chr9:136,796,338–136,866,308, 11 genes, copy number 7 (within-gene range 2–7): CCDC183, AL355987.4, AL355987.2, CCDC183-AS1, RABL6, NCLP1, MIR4292, AJM1, PHPT1, MAMDC4, EDF1.
- chr9:136,935,840–138,253,217, 75 genes, copy number 5–8 (broad region; genes not listed).
- chr10:14,061–50,625,163, 869 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:49,827,913–49,977,139, 12 genes, copy number 5 (within-gene range 3–5): BCDIN3D-AS1, BCDIN3D, AC131157.1, RPL35AP28, FAIM2, LINC02395, LINC02396, AQP2, AC025154.2, AC025154.1, AQP5, AQP6.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:20,311,368–20,413,501, 9 genes, copy number 5: CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1.
- chr16:9,355,588–9,518,325, 4 genes, copy number 7: LINC02177, AC012178.1, LINC01177, LINC01195.
- chr16:11,668,455–11,828,845, 7 genes, copy number 13: SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr16:14,407,668–15,643,154, 48 genes, copy number 7–10: AC040173.1, PARN, RN7SL274P, BFAR, RNU7-125P, PLA2G10, AC009167.1, NPIPA3, AC136443.1, AC136443.4, NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1, AC138932.3, PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3, AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1, AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506.
- chr16:16,499,533–16,953,468, 4 genes, copy number 5–11: AC136431.1, AC136619.2, AC092326.1, AC098965.1.
- chr16:21,794,095–22,576,865, 29 genes, copy number 10: AC092375.2, RRN3P1, AC092375.3, NPIPB4, SMG1P4, AC092375.1, AC092119.2, UQCRC2, PDZD9, AC092119.1, AC092119.3, MOSMO, AC009019.1, VWA3A, SDR42E2, AC009019.2, EEF2K, AC009034.1, POLR3E, AC092338.3, CDR2, AC092338.1, AC092338.2, MFSD13B, RRN3P3, SMG1P1, NPIPB5, AC106788.1, OTOAP1.
- chr16:23,753,689–24,495,177, 12 genes, copy number 5–11: AC012317.2, CHP2, PRKCB, AC130454.1, AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1.
- chr16:25,085,168–25,261,066, 10 genes, copy number 13: LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT.
- chr16:27,066,707–27,549,913, 13 genes, copy number 7–13: C16orf82, AC092725.1, EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1.
- chr16:30,378,106–30,400,108, 1 gene, copy number 8 (within-gene range 2–8): ZNF48.
- chr16:30,407,414–31,231,537, 88 genes, copy number 6–8 (broad region; genes not listed).
- chr16:31,456,711–31,569,475, 16 genes, copy number 11–12: AC026471.1, ARMC5, AC026471.6, TGFB1I1, SLC5A2, AC026471.3, RUSF1, AC026471.2, AHSP, LINC02190, AC106730.1, VN1R64P, VN1R65P, FRG2KP, AC106730.2, YBX3P1.
- chr16:32,649,193–34,268,649, 84 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–27,984,984, 8 genes, copy number 5–6 (within-gene range 4–6): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5.
- chr19:27,902,595–35,169,881, 176 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:37,312,837–58,605,223, 1,360 genes, copy number 5–8 (broad region; genes not listed).
- chr20:30,484,925–64,327,972, 862 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 797. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
